Gene-level copy-number profile of specimen HCM-BROD-1129-C56-85B from HCMI case HCM-BROD-1129-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 61.4 years (22,421 days).
Specimen HCM-BROD-1129-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f14c0b3f-3f9f-43bd-b07d-4194f2cc3210.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1129-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/8941abaa-3989-4cbb-8593-99e93fc983e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 16,274; copy number 2: 33,634; copy number 3: 6,880; copy number 4: 1,296; copy number 5: 134; copy number 6: 31; copy number 7: 109.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:4,242,056–4,279,192, 2 genes: SSU72P2, SSU72P6.
- chr12:83,661,009–88,142,099, 34 genes: AC093025.1, AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1.
- chr13:48,296,162–48,599,436, 7 genes (within-gene range 0–1): RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 274 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,682,108–246,768,137, 4 genes, copy number 5: AL591848.2, AL591848.1, SCCPDH, RPL35AP6.
- chr5:710,355–1,523,962, 27 genes, copy number 6: ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr7:21,215,537–21,215,830, 1 gene, copy number 7: RN7SL542P.
- chr8:127,289,817–127,482,139, 1 gene, copy number 5 (within-gene range 4–5): CASC8.
- chr8:127,322,183–128,564,679, 18 genes, copy number 5: POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:129,241,228–129,251,138, 2 genes, copy number 5: AC103833.2, AC103833.1.
- chr8:135,859,369–145,066,685, 217 genes, copy number 5–7 (broad region; genes not listed).
- chr9:71,683,366–71,911,193, 4 genes, copy number 6: CEMIP2, AL671309.1, ABHD17B, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 16,274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
